CCDI case PBCAJH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/58cd899a-6eb3-4f6a-9ca8-70aeaac041c8

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 8.3 years (3,026 days).

Biospecimens (3 samples)
- Sample 0DMBLL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMBM5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMBMD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
